Gene-level copy-number profile of tumor specimen TCGA-DK-A1AA-01A from TCGA case TCGA-DK-A1AA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-DK-A1AA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.df65dfac-018b-41e5-8ccf-ba7576b39305.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1AA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b07fb5f0-c41e-46dd-ba79-50ef69007004

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 4,994; copy number 2: 54,317; copy number 3: 723; copy number 4: 131.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1AA-01A-11D-A13V-01): tumor purity 0.93, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,616,137, 4 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr9:20,341,669–24,088,051, 80 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:74,371,335–75,724,575, 21 genes: AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–2): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,613. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
